Gene-level copy-number profile of tumor specimen CDDP-ABKV-TTP1-A from CDDP_EAGLE case CDDP-ABKV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57 years.
Specimen CDDP-ABKV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94238eab-8d7b-4984-8ec4-8ae59173b5d0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABKV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/c011f672-828b-4482-97cd-b826a7647e07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 371; copy number 1: 25,192; copy number 2: 27,552; copy number 3: 4,751; copy number 4: 808; copy number 5: 178; copy number 6: 60.

Homozygous deletions (total copy number 0; autosomes only): 370 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–15,325,569, 358 genes (broad region; genes not listed).
- chr9:21,802,636–22,046,901, 12 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 238 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:49,960,249–49,969,625, 2 genes, copy number 5: DEFB114, DEFB113.
- chr8:111,376,639–111,757,710, 3 genes, copy number 5: LINC02237, SERPINA15P, H2AZP7.
- chr8:116,845,934–132,111,159, 212 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:134,477,788–135,742,495, 21 genes, copy number 5: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.

Autosomal genes at a single copy (total copy number 1): 22,337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
